Gene-level copy-number profile of tumor specimen TARGET-40-PAKUZU-01A from TARGET case TARGET-40-PAKUZU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,270 days).
Specimen TARGET-40-PAKUZU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.48e450a3-d303-5ed0-9c89-2f5d1640ab5d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAKUZU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 410 have no estimate.
https://portal.gdc.cancer.gov/files/ff034ea1-b0cd-4402-88c7-113bf8d7601a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 3,753; copy number 2: 15,456; copy number 3: 29,969; copy number 4: 7,154; copy number 5: 2,044; copy number 6: 783; copy number 7: 534; copy number 8: 208; copy number 9: 64; copy number 10: 51; copy number 11: 18; copy number 12: 55; copy number 13: 14.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr4:68,509,441–68,616,137, 4 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 944 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,294,835–247,294,941, 1 gene, copy number 9: Y_RNA.
- chr2:52,864,235–52,866,631, 1 gene, copy number 8 (within-gene range 3–8): AC010967.2.
- chr3:123,563–133,500, 1 gene, copy number 7: AC066595.2.
- chr6:39,188,971–39,322,968, 3 genes, copy number 7: KCNK5, KCNK17, KCNK16.
- chr6:39,353,747–39,354,172, 1 gene, copy number 7: AL136087.1.
- chr6:41,546,426–42,181,338, 28 genes, copy number 7: FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A.
- chr6:46,903,471–46,909,078, 1 gene, copy number 8: ADGRF5-AS1.
- chr7:129,117,513–130,388,114, 36 genes, copy number 8: CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1.
- chr8:85,642,777–86,212,236, 21 genes, copy number 7 (within-gene range 3–7): REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1.
- chr8:90,592,804–92,144,435, 23 genes, copy number 7: LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1.
- chr8:95,986,108–97,277,928, 18 genes, copy number 11: AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA, AP003548.1, RNU6-1172P, SDC2, CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5.
- chr8:98,371,228–98,942,827, 1 gene, copy number 9 (within-gene range 4–9): STK3.
- chr8:98,436,669–115,809,673, 232 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:118,189,455–131,712,980, 201 genes, copy number 7–13 (broad region; genes not listed).
- chr8:132,507,962–133,963,259, 31 genes, copy number 7–10: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:144,584,040–145,066,685, 23 genes, copy number 7: AC084125.3, Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:25,579,657–25,844,585, 3 genes, copy number 8 (within-gene range 3–8): AL353730.1, TUSC1, LINC01241.
- chr11:80,321,620–81,556,425, 9 genes, copy number 7: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 7: AP002802.2, MIR4300, AP002802.1.
- chr11:90,049,945–90,226,538, 14 genes, copy number 7: AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1.
- chr11:97,878,475–105,531,697, 93 genes, copy number 7–13 (broad region; genes not listed).
- chr11:126,423,358–127,006,058, 9 genes, copy number 7 (within-gene range 3–7): KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3.
- chr19:38,587,641–41,652,963, 182 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:52,192,159–52,890,386, 9 genes, copy number 7 (within-gene range 3–7): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1.

Autosomal genes at a single copy (total copy number 1): 1,642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
